Gene-level copy-number profile of tumor specimen TCGA-A7-A2KD-01A from TCGA case TCGA-A7-A2KD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.6 years (19,563 days).
Specimen TCGA-A7-A2KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.647c33ff-55fa-43b7-91ef-eb63ab47a549.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A2KD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68534f90-1ce8-4bee-8d72-ee989ce2ef7a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 502; copy number 2: 5,766; copy number 3: 19,614; copy number 4: 20,847; copy number 5: 7,021; copy number 6: 1,481; copy number 7: 754; copy number 8: 2,042; copy number 9: 457; copy number 10: 762; copy number 11: 120; copy number 12: 63; copy number 13: 156; copy number 14: 11; copy number 16: 41; copy number 19: 81; copy number 41: 74; copy number 58: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A2KD-01A-31D-A21P-01): tumor purity 0.55, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,567,423–22,706,703, 5 genes: AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,769 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:76,980,258–80,484,481, 38 genes, copy number 9–58 (within-gene range 7–58): PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1.
- chr9:33,104,082–36,304,924, 168 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr10:7,486,703–7,536,565, 2 genes, copy number 11: RNU6-535P, AL445070.1.
- chr10:8,513,687–17,454,595, 138 genes, copy number 9–19 (broad region; genes not listed).
- chr10:23,694,746–24,547,848, 6 genes, copy number 10: KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1.
- chr10:49,551,308–50,279,720, 21 genes, copy number 10: HMGB1P50, CHAT, SLC18A3, C10orf53, OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1.
- chr10:50,325,697–50,341,585, 2 genes, copy number 10: AC069547.2, AC069547.1.
- chr10:61,662,929–65,880,289, 43 genes, copy number 9 (within-gene range 6–9): CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr10:81,870,778–81,875,133, 1 gene, copy number 10: AL096706.1.
- chr10:120,925,547–123,150,672, 42 genes, copy number 10 (within-gene range 3–10): AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2.
- chr12:66,767–1,647,212, 32 genes, copy number 10 (within-gene range 8–10): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14.
- chr12:23,108,458–29,784,759, 116 genes, copy number 9–19 (broad region; genes not listed).
- chr17:26,981,694–27,170,310, 7 genes, copy number 9 (within-gene range 3–9): AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2.
- chr17:38,195,703–39,919,854, 74 genes, copy number 41 (broad region; genes not listed).
- chr17:63,622,415–63,696,305, 1 gene, copy number 9 (within-gene range 6–9): MAP3K3.
- chr17:63,682,336–69,903,000, 170 genes, copy number 9 (broad region; genes not listed).
- chr17:74,203,582–76,738,522, 148 genes, copy number 10 (broad region; genes not listed).
- chr17:76,736,450–76,753,015, 2 genes, copy number 10: MIR636, RNU6-97P.
- chr17:77,590,532–83,095,122, 237 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr18:58,631,259–62,650,601, 76 genes, copy number 11 (broad region; genes not listed).
- chr19:13,731,760–14,565,980, 51 genes, copy number 13: CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.3, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639.
- chr19:21,709,522–22,861,594, 61 genes, copy number 12 (broad region; genes not listed).
- chr20:45,091,214–48,494,309, 126 genes, copy number 10–13 (broad region; genes not listed).
- chr20:48,657,073–48,659,119, 1 gene, copy number 13: AL035106.1.
- chr20:49,632,945–53,741,797, 83 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:62,352,995–64,313,132, 123 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 502. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
